Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A023, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A023-01A (Primary Tumor).

Sample ID #

Diagnosis:

Preparation I) is an invasive colonic adenocarcinoma type of carcinoma, of moderate differentiation, G2,

with infiltration of all parietal layers, pT3,

invasions of lymph and blood vessels (L1, V1),

and also substantial concomitant inflammation.

As regards the lymph nodes, there are also sox sections of lymph node metastases of the carcinoma described (pN2),

in the attached segment there is a squamous epithelial mucosa that is infiltrated by a tumor from the outside,

as regards the resection margins of the mucosa and the ligature area, the tumor was completely removed.

Preparation II) comprises smooth muscle fiber elements, possibly from the area close to the tubes, with further extensive portions of the carcinoma

Preparation III) comprises regular anastomosis rings, in this case of the cryptic epithelium type with attached submucosa and muscularis.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: Rectum C20.9

for 3/31/11

Source: NCI Genomic Data Commons file 3e08e2aa-bac3-422c-a084-9010b0f9b6fc (TCGA-AG-A023.F8E2C216-9EAE-414F-A989-1A6B0D720522.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).